Somatic mutation profile of tumor specimen TARGET-40-PAUHGA-01A (aliquot TARGET-40-PAUHGA-01A-01D) from TARGET case TARGET-40-PAUHGA, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 14.3 years (5,226 days).
Specimen TARGET-40-PAUHGA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cc9de0f-c7fd-40b5-8eaa-f2418170d393.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAUHGA-10A (Blood Derived Normal), aliquot TARGET-40-PAUHGA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78a66c61-6cce-404b-afdd-2db6211bbee3

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUCL3 | c.890A>C p.N297T | Missense Mutation (SNP) | VAF 48/444 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868295857, COSV58516355; called by mutect2, varscan2
- MYO15A | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 33/730 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV52763193; called by muse, mutect2
- UNC13C | c.367A>T p.I123F | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs547772270; called by muse, mutect2, varscan2
- WBP2NL | c.672C>A p.Y224* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as rs901271525, COSV60920767; called by mutect2, varscan2
- MXRA5 | c.208_209del p.L70Vfs*20 | Frame Shift Del (DEL) | VAF 9/17 reads (53%) | called by mutect2, pindel, varscan2
- TICRR | c.2019G>A p.M673I | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSPAN12 | c.84G>C p.V28= | Silent (SNP) | VAF 10/70 reads (14%) | called by mutect2, varscan2
- GON4L | c.6473+9G>A | Intron (SNP) | VAF 44/369 reads (12%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-759G>C | Intron (SNP) | VAF 120/779 reads (15%) | catalogued as rs140827661, COSV58518173; called by muse, varscan2
